Somatic mutation profile of tumor specimen MMRF_2091_1_BM_CD138pos (aliquot MMRF_2091_1_BM_CD138pos_T1_KHS5U_L08136) from MMRF case MMRF_2091, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.7 years (18,143 days).
Specimen MMRF_2091_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68434b98-e224-4339-8bc2-693573fbe15c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2091_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2091_1_PB_Whole_C2_KHS5U_L08137; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59adc925-a9cd-4e0b-a1e5-70848ccd00a2

The open-access MAF lists 820 somatic variants for this specimen: 297 protein-altering or splice-affecting, 124 silent, 399 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, 3'UTR 172, Silent 124, Intron 110, 5'UTR 69, 5'Flank 26, Nonsense Mutation 23, 3'Flank 13, RNA 9, Splice Region 7, Splice Site 5, Frame Shift Del 3.

Variants (750 of 820; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SACS | c.5414C>G p.S1805* | Nonsense Mutation (SNP) | VAF 126/139 reads (91%) | catalogued as rs1555252113; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs775434031, COSV60691421; called by muse, mutect2, varscan2
- ACAA1 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs754009365; called by muse, mutect2, varscan2
- AEBP1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV99788842; called by muse, mutect2, varscan2
- AFAP1L2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs17852236, COSV100413157; called by muse, mutect2, varscan2
- AGPAT4 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57243767; called by muse, mutect2, varscan2
- ANK3 | c.5698G>A p.E1900K | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs866519056; called by muse, mutect2, varscan2
- ANTXR2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs773818652; called by muse, mutect2, varscan2
- APCDD1L | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560237850, COSV100953921; called by muse, mutect2, varscan2
- ARHGAP21 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 36/68 reads (53%) | catalogued as COSV57605833; called by muse, mutect2, varscan2
- ARL4C | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100327071, COSV60214738; called by muse, mutect2, varscan2
- ATP6V1B1 | c.522G>C p.M174I | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV52271750; called by muse, mutect2, varscan2
- BAZ2B | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs763350917, COSV58599852; called by muse, mutect2, varscan2
- BNC2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 195/409 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.091); catalogued as rs780872323; called by muse, mutect2, varscan2
- BNC2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.516); catalogued as rs1480278008, COSV66156292; called by muse, mutect2, varscan2
- C11orf52 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 123/252 reads (49%) | catalogued as rs1555166929; called by muse, mutect2, varscan2
- C11orf54 | c.802C>T p.H268Y (on ENST00000331239; = p.H218Y on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776217133; called by muse, mutect2, varscan2
- C15orf40 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.237); catalogued as rs565635076, COSV55603757; called by muse, mutect2, varscan2
- CACNG7 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs763217669; called by muse, mutect2, varscan2
- CAND2 | c.2845G>A p.E949K (on ENST00000456430 / NM_001162499.2; = p.E856K on NM_012298.3) | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201393756, COSV55989772; called by muse, mutect2, varscan2
- CARD10 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs760193849, COSV99325147; called by muse, mutect2, varscan2
- CCT8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs1161895499; called by muse, mutect2, varscan2
- CDH23 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs760093031; called by muse, mutect2, varscan2
- CDH26 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54848350; called by muse, mutect2, varscan2
- CDH9 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 175/379 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs267600596, COSV50253768; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1066C>T p.H356Y (on ENST00000357886 / NM_001365728.1; = p.H342Y on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100211849; called by muse, mutect2, varscan2
- CFAP52 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1361072712, COSV55343747; called by muse, mutect2
- CFAP54 | c.7499C>T p.S2500F | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs746759832; called by muse, mutect2, varscan2
- CLSTN3 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs749934859; called by muse, mutect2, varscan2
- CSNK2A1 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53937698, COSV99424385; called by muse, mutect2, varscan2
- DNAH1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 75/120 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1388082908; called by muse, mutect2, varscan2
- DNAH5 | c.2881C>G p.H961D | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54211935, COSV54245362; called by muse, mutect2, varscan2
- DTNBP1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775943974; called by muse, mutect2, varscan2
- DUSP2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | catalogued as rs1428919005; called by muse, mutect2, varscan2
- EHD4 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs768556393; called by muse, mutect2, varscan2
- EIF1AX | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63309422, COSV63309489; called by muse, mutect2
- ENPP6 | c.531C>T p.F177= | Splice Region (SNP) | VAF 165/356 reads (46%) | catalogued as COSV99698882; called by muse, mutect2, varscan2
- EPG5 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs754502344; called by muse, mutect2
- F2R | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753091887; called by muse, mutect2, varscan2
- FAT1 | c.8362G>C p.E2788Q | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV101499676; called by muse, mutect2, varscan2
- GAS8 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs548463078, COSV99244020; called by muse, mutect2, varscan2
- GPRC5C | c.1137G>C p.Q379H (on ENST00000652232; = p.Q334H on NM_018653.4) | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100702805; called by muse, mutect2, varscan2
- GRAMD1B | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100454135, COSV100454891; called by muse, mutect2, varscan2
- H1-3 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs765867901; called by muse, mutect2, varscan2
- H2AC12 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs745469676, COSV63617369, COSV63617773; called by muse, mutect2, varscan2
- H2AC12 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs748144337; called by muse, mutect2, varscan2
- H4C3 | c.311G>C p.*104Sext*2 | Nonstop Mutation (SNP) | VAF 100/270 reads (37%) | catalogued as COSV58091110; called by muse, mutect2
- HNRNPM | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV57691725, COSV57692018; called by muse, mutect2, varscan2
- IER2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs573519474; called by muse, mutect2, varscan2
- IGHD2-2 | c.18C>G p.Y6* | Nonsense Mutation (SNP) | VAF 24/24 reads (100%) | catalogued as rs374987557; called by muse, varscan2
- IGHV1-69 | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs374276673; called by muse, mutect2, varscan2
- IGHV2-70 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs373599438; called by muse, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- IGHV2-70 | c.52T>A p.L18I | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs543742874; called by muse, varscan2
- IGHV3-30 | c.233A>C p.Y78S | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as rs773153070; called by muse, mutect2
- IGHV3-33 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); catalogued as rs371531100; called by muse, varscan2
- IGLV3-1 | c.308A>C p.D103A | Missense Mutation (SNP) | VAF 64/67 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs376677833; called by muse, varscan2
- ITFG1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs1191863805; called by muse, mutect2, varscan2
- ITGB1BP2 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.662); catalogued as COSV52139993; called by muse, mutect2, varscan2
- KCNH6 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59001926; called by muse, mutect2
- KCNH8 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs373577840; called by muse, mutect2, varscan2
- KCNK17 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as COSV64686439; called by muse, mutect2, varscan2
- KCTD12 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs750568955; called by muse, mutect2, varscan2
- KIAA1210 | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 118/232 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV101274462; called by muse, varscan2
- KIF15 | c.3108G>C p.Q1036H | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs377167940; called by muse, mutect2
- LIX1L | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs782422147; called by muse, mutect2, varscan2
- LPA | c.5075G>A p.R1692Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60304580; called by muse, mutect2, varscan2
- LRIT2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1433124911, COSV60567332; called by muse, mutect2, varscan2
- MAP3K1 | c.3595C>T p.Q1199* | Nonsense Mutation (SNP) | VAF 153/340 reads (45%) | catalogued as COSV68123235; called by muse, mutect2, varscan2
- MARF1 | c.4683G>A p.M1561I | Missense Mutation (SNP) | VAF 129/251 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as rs1388129129, COSV104417590; called by muse, mutect2, varscan2
- MAST3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs971458049, COSV53220818; called by muse, mutect2, varscan2
- MROH2B | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV68189434; called by muse, mutect2, varscan2
- NFATC3 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1201433380; called by muse, varscan2
- NOS3 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757138786; called by muse, mutect2, varscan2
- OPCML | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 121/268 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100101801; called by muse, mutect2, varscan2
- OR52B4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs372707235; called by muse, mutect2, varscan2
- OR5C1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV65455859; called by muse, mutect2
- PARD6G | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs1036144243, COSV62060213; called by muse, mutect2, varscan2
- PCDHA10 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV56476457; called by muse, mutect2
- PCLO | c.4858G>A p.D1620N | Missense Mutation (SNP) | VAF 33/611 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100430730; called by muse, mutect2
- PENK | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100152238, COSV59242846; called by muse, mutect2, varscan2
- PHF1 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); catalogued as rs1187220918; called by muse, mutect2, varscan2
- PLAGL1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs749708141, COSV52786342; called by muse, mutect2, varscan2
- PPP2R5A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1198599806; called by muse, mutect2, varscan2
- PRKAR2B | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs758303446; called by muse, mutect2, varscan2
- PRKCG | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as COSV54723587; called by muse, mutect2, varscan2
- PXK | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV57088879; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RB1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117842; called by muse, mutect2, varscan2
- RDH13 | c.491C>A p.S164* (on ENST00000415061 / NM_001145971.2; = p.S93* on NM_138412.4) | Nonsense Mutation (SNP) | VAF 78/174 reads (45%) | catalogued as COSV52560258, COSV52562625; called by muse, mutect2, varscan2
- RELN | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58987245; called by muse, mutect2, varscan2
- RFC4 | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 5/141 reads (4%) | catalogued as COSV56215828; called by muse, mutect2
- RNASEL | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); catalogued as COSV100842608; called by muse, mutect2, varscan2
- RPS21 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs765716910; called by muse, mutect2, varscan2
- RYBP | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101523277, COSV72180790; called by muse, mutect2, varscan2
- RYR2 | c.4599G>A p.V1533= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as COSV63704162; called by muse, mutect2, varscan2
- SACS | c.10462C>T p.L3488F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV66543504; called by muse, mutect2, varscan2
- SBF1 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs528597678, COSV100817751; called by muse, mutect2, varscan2
- SCAF11 | c.3311C>T p.S1104L | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65476705; called by muse, mutect2, varscan2
- SCML1 | c.376G>A p.E126K (on ENST00000380041 / NM_001037540.3; = p.E99K on NM_006746.6) | Missense Mutation (SNP) | VAF 194/439 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs771791797, COSV101193919; called by muse, mutect2, varscan2
- SCN5A | c.3926G>A p.R1309H (on ENST00000333535 / NM_198056.3; = p.R1308H on NM_000335.5) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs537423012, CM161192, COSV100346961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELE | c.213G>C p.W71C | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60975769; called by muse, mutect2, varscan2
- SELENOS | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV68011480; called by muse, mutect2, varscan2
- SLC26A1 | c.1302C>G p.F434L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758993299; called by muse, mutect2
- SLC28A1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 9/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035660741, COSV54481385; called by muse, mutect2
- SPN | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs143508591; called by muse, mutect2, varscan2
- SPTA1 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63749134, COSV63751651; called by muse, mutect2, varscan2
- SSH2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV52172777; called by muse, mutect2, varscan2
- STARD10 | c.578-5C>T | Splice Region (SNP) | VAF 80/167 reads (48%) | catalogued as rs1286461149; called by muse, mutect2, varscan2
- SYNE1 | c.7342G>A p.D2448N (on ENST00000367255 / NM_182961.4; = p.D2455N on NM_033071.3) | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1250614595; called by muse, mutect2, varscan2
- TAF4B | c.2505C>G p.I835M | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV52306417; called by muse, mutect2, varscan2
- TFPI | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99259052; called by muse, mutect2, varscan2
- TMC1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52785907; called by muse, mutect2, varscan2
- TMC5 | c.2496G>A p.M832I (on ENST00000396229 / NM_001105248.1; = p.M586I on NM_024780.5) | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs866704826; called by muse, mutect2, varscan2
- TMPRSS11D | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV52226921; called by muse, mutect2, varscan2
- TRPS1 | c.3191G>C p.R1064T (on ENST00000220888 / NM_001330599.2; = p.R1077T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99635065; called by muse, mutect2, varscan2
- TTC17 | c.543G>C p.E181D | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); catalogued as COSV50006049; called by muse, mutect2
- TTC22 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV64882047; called by muse, mutect2, varscan2
- TXNDC5 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); catalogued as rs374144052, COSV51668295; called by muse, mutect2, varscan2
- UAP1L1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs146965332; called by muse, mutect2, varscan2
- UGT3A2 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56928036; called by muse, mutect2
- UNC80 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs912759198; called by muse, mutect2
- VAX1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1451874313; called by muse, mutect2, varscan2
- VPS50 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 107/230 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1234607384; called by muse, mutect2, varscan2
- VWA7 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65173992; called by muse, mutect2, varscan2
- WBP11 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 225/534 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.145); catalogued as COSV53761982; called by muse, mutect2, varscan2
- WIPF2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1392706520; called by muse, mutect2, varscan2
- YTHDF2 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65723132; called by muse, mutect2, varscan2
- ABCA4 | c.6507G>C p.M2169I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABI3BP | c.3109C>G p.R1037G | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM22 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AHNAK | c.13495G>A p.E4499K | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ALDH1L1 | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ANLN | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- AP002512.3 | c.574_599del p.T192Lfs*24 | Frame Shift Del (DEL) | VAF 82/256 reads (32%) | called by mutect2, pindel, varscan2
- APPBP2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARHGEF2 | c.469G>C p.G157R (on ENST00000361247 / NM_001162383.2; = p.G130R on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF5 | c.2498C>G p.S833* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- ARL8B | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- BAD | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- BAMBI | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- BCL9L | c.2627C>T p.S876L | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BPTF | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- BTD | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CABP5 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CCDC168 | c.17317G>C p.E5773Q | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CCDC27 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC40 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 87/97 reads (90%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CD99L2 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 132/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CEP164 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- CEP350 | c.6529G>C p.E2177Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CFTR | c.2901G>C p.L967F | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CHD1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHSY1 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNOT2 | c.1241-1G>A p.X414_splice | Splice Site (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- COMMD1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CPSF2 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CRYL1 | c.277-3C>T | Splice Region (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- CXorf65 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DDX41 | c.273C>G p.H91Q | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DISC1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2
- DOCK2 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- DRGX | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EHD1 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 194/435 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EIF1B | c.30C>T p.F10= | Splice Region (SNP) | VAF 255/476 reads (54%) | called by muse, mutect2, varscan2
- ERN1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXD3 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXOC5 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- FAM186B | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM217A | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FAM50A | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- FANCI | c.2440C>G p.L814V | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FAT3 | c.713T>A p.M238K | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAT3 | c.13136G>C p.G4379A | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- FGF8 | c.356G>C p.G119A (on ENST00000344255 / NM_033164.4; = p.G101A on NM_006119.6) | Missense Mutation (SNP) | VAF 149/351 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 60/132 reads (45%) | called by muse, mutect2, varscan2
- FN1 | c.1935G>A p.W645* | Nonsense Mutation (SNP) | VAF 78/170 reads (46%) | called by muse, mutect2, varscan2
- FRAS1 | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FRS2 | c.1340C>G p.S447C | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); called by muse, mutect2
- FSCN3 | c.841+2C>T p.X281_splice | Splice Site (SNP) | VAF 51/97 reads (53%) | called by muse, mutect2, varscan2
- GABPA | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- GAD2 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIPC3 | c.4009C>G p.L1337V | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GLIS3 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2
- GOLPH3L | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPD2 | c.661+2T>A p.X221_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- GRIA1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HCFC1 | c.3596G>C p.R1199P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELB | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.053); called by muse, varscan2
- HNF4G | c.215G>A p.C72Y (on ENST00000354370 / NM_001330561.2; = p.C119Y on NM_004133.5) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK2 | c.258C>T p.V86= | Splice Region (SNP) | VAF 77/199 reads (39%) | called by muse, mutect2, varscan2
- HSPBAP1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HYPK | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.921); called by muse, mutect2
- IARS2 | c.2947A>G p.T983A | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- IFT172 | c.4921G>C p.E1641Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 84/387 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-33 | c.233A>C p.Y78S | Missense Mutation (SNP) | VAF 130/252 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); called by muse, varscan2
- IGLC2 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS5 | c.1596G>C p.L532F | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- KCNA4 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 92/174 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNA6 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA0319L | c.2745C>G p.I915M | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KIAA1958 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | called by muse, mutect2, varscan2
- LGALS8 | c.901G>A p.D301N (on ENST00000341872; = p.D343N on NM_006499.4) | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LIX1L | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- LPL | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 138/164 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC69 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- MACF1 | c.19150G>C p.E6384Q (on ENST00000372915; = p.E4429Q on NM_012090.5) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- MAGEA4 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MAGI1 | c.3823C>G p.Q1275E | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MARK3 | c.1543A>C p.T515P | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAX | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
- MBD5 | c.4439G>C p.R1480T | Missense Mutation (SNP) | VAF 281/647 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MBOAT1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MCM3AP | c.2399G>C p.C800S | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MCM5 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, varscan2
- MED7 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MGAM2 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAT5B | c.1727G>A p.R576K (on ENST00000569840 / NM_001199172.2; = p.R574K on NM_144677.3) | Missense Mutation (SNP) | VAF 145/334 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MICAL3 | c.3529G>C p.E1177Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKKS | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MON2 | c.3372G>T p.R1124S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MSX2 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MYEF2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYH7 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAALADL1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- NACAD | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- NAXE | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NID2 | c.1770T>A p.F590L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NME6 | c.541G>A p.G181R (on ENST00000415053; = p.G189R on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- NOL11 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10J1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 211/431 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- OR10Q1 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- OR5AR1 | c.864G>C p.L288F | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- OTOF | c.3565G>C p.E1189Q (on ENST00000272371 / NM_194248.3; = p.E442Q on NM_004802.4) | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PASD1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PCDHGC4 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCF11 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PDCD1 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PDE10A | c.1975C>G p.Q659E | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDSS2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- PEX1 | c.2814C>G p.F938L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM2 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 81/156 reads (52%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.4224G>A p.M1408I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PMPCB | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- POM121 | c.1368-1G>A p.X456_splice (on ENST00000434423; = p.X191_splice on NM_172020.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2, varscan2
- POP1 | c.1589G>T p.C530F | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD5 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 143/305 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPN13 | c.2429G>C p.G810A | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUM1 | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RAG1 | c.2556G>A p.M852I | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- RANBP17 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2
- RET | c.2019G>C p.E673D | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2
- ROBO2 | c.1084del p.Q362Sfs*33 | Frame Shift Del (DEL) | VAF 44/256 reads (17%) | called by mutect2, pindel, varscan2
- ROBO2 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2
- RYR2 | c.4600G>C p.E1534Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD15 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 187/227 reads (82%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SDC4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- SENP6 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SIRPA | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- SIRT5 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 157/330 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- SLC17A8 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC23A1 | c.769-7C>A | Splice Region (SNP) | VAF 96/196 reads (49%) | called by muse, mutect2, varscan2
- SLC7A6OS | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SLC9A3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMPD4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SOX17 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SP140 | c.2284-1G>A p.X762_splice | Splice Site (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- SPN | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SPN | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SRCAP | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 167/362 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SSTR4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSUH2 | c.661del p.E221Rfs*91 | Frame Shift Del (DEL) | VAF 117/353 reads (33%) | called by mutect2, pindel, varscan2
- STOX2 | c.1970C>A p.S657* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- STRC | c.4734G>C p.Q1578H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SULF1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- SUZ12 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SYCP2L | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYT4 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TACC3 | c.2244G>C p.K748N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TAOK1 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 5/136 reads (4%) | called by muse, mutect2
- TEKT5 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 71/87 reads (82%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TESPA1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THUMPD2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMCC2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEM132E | c.2582C>A p.S861* (on ENST00000321639; = p.S951* on NM_001304438.2) | Nonsense Mutation (SNP) | VAF 99/161 reads (61%) | called by muse, mutect2, varscan2
- UAP1L1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBTF | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- USP34 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP43 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- VCAN | c.8069C>T p.A2690V | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YAF2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF135 | c.388G>A p.E130K (on ENST00000313434 / NM_001289401.2; = p.E142K on NM_003436.4) | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF502 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZNF735 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- ZNF839 | c.97C>T p.Q33* (on ENST00000558850 / NM_001267827.1; = p.Q149* on NM_018335.5) | Nonsense Mutation (SNP) | VAF 138/257 reads (54%) | called by muse, mutect2, varscan2
- ZNF92 | c.1345G>T p.E449* (on ENST00000328747 / NM_152626.4; = p.E380* on NM_007139.4) | Nonsense Mutation (SNP) | VAF 62/168 reads (37%) | called by muse, mutect2, varscan2
- ABCC12 | c.180C>G p.L60= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV60914648; called by muse, mutect2, varscan2
- ABCG4 | c.1284C>T p.F428= | Silent (SNP) | VAF 138/290 reads (48%) | catalogued as rs771715518; called by muse, mutect2, varscan2
- ADAMTS12 | c.2481C>T p.F827= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV100711685; called by muse, mutect2, varscan2
- ADGRD1 | c.1233C>A p.P411= | Silent (SNP) | VAF 79/232 reads (34%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1083G>A p.L361= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs777234752; called by muse, mutect2, varscan2
- ARID2 | c.2874G>A p.Q958= | Silent (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- BANK1 | c.1293G>A p.Q431= | Silent (SNP) | VAF 55/224 reads (25%) | called by muse, mutect2, varscan2
- BCL9L | c.3840G>A p.L1280= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs1239369025; called by muse, mutect2, varscan2
- BOP1 | c.1398C>T p.P466= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1025796495; called by muse, mutect2, varscan2
- BPIFB3 | c.321G>A p.L107= | Silent (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- C6orf120 | c.570C>G p.L190= | Silent (SNP) | VAF 95/226 reads (42%) | catalogued as rs774247533; called by muse, mutect2, varscan2
- CACNA1B | c.3162G>A p.Q1054= | Silent (SNP) | VAF 102/268 reads (38%) | called by muse, mutect2, varscan2
- CAV3 | c.90G>A p.K30= | Silent (SNP) | VAF 18/452 reads (4%) | called by muse, mutect2
- CCDC65 | c.1008G>C p.L336= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV99872809, COSV99872871; called by muse, mutect2, varscan2
- CDH23 | c.3822G>A p.E1274= | Silent (SNP) | VAF 37/556 reads (7%) | called by muse, mutect2
- CEP290 | c.2832C>T p.F944= | Silent (SNP) | VAF 86/211 reads (41%) | catalogued as COSV58355490; called by muse, mutect2, varscan2
- CFAP100 | c.588C>T p.D196= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1409999870, COSV100729004; called by muse, mutect2, varscan2
- CLASP1 | c.1551C>T p.F517= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV55341153; called by muse, mutect2, varscan2
- CNTNAP1 | c.2307C>A p.A769= | Silent (SNP) | VAF 123/237 reads (52%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4014C>T p.L1338= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs1222066120; called by muse, mutect2, varscan2
- CUX2 | c.2130G>A p.A710= | Silent (SNP) | VAF 39/64 reads (61%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.15G>A p.K5= | Silent (SNP) | VAF 154/375 reads (41%) | called by muse, mutect2, varscan2
- DLEC1 | c.4287C>T p.F1429= | Silent (SNP) | VAF 148/337 reads (44%) | called by muse, mutect2, varscan2
- DNAJB1 | c.477G>A p.K159= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- DRC1 | c.666C>G p.L222= | Silent (SNP) | VAF 40/71 reads (56%) | catalogued as COSV56530295, COSV99985338; called by muse, mutect2, varscan2
- DUOX1 | c.897C>T p.F299= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- DUSP2 | c.405C>T p.F135= | Silent (SNP) | VAF 87/177 reads (49%) | called by muse, mutect2, varscan2
- EHMT2 | c.1335G>A p.K445= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs1319452905; called by muse, mutect2, varscan2
- EMILIN3 | c.789G>A p.Q263= | Silent (SNP) | VAF 81/160 reads (51%) | called by muse, mutect2, varscan2
- FAM161A | c.81C>T p.V27= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs1348815152, COSV56767576; called by muse, mutect2
- FAM205A | c.1584G>A p.Q528= | Silent (SNP) | VAF 111/368 reads (30%) | catalogued as COSV66490173; called by muse, mutect2, varscan2
- FANCA | c.4311G>A p.Q1437= | Silent (SNP) | VAF 41/43 reads (95%) | called by muse, mutect2, varscan2
- FBLN2 | c.2247C>T p.L749= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- FGFRL1 | c.1206G>A p.Q402= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as rs1443502789; called by muse, mutect2, varscan2
- FILIP1 | c.846C>G p.L282= | Silent (SNP) | VAF 87/229 reads (38%) | called by muse, mutect2, varscan2
- FO681492.1 | c.1254G>C p.L418= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- GALNT17 | c.48C>T p.I16= | Silent (SNP) | VAF 136/289 reads (47%) | called by muse, mutect2, varscan2
- GMEB2 | c.282C>T p.I94= | Silent (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- GPR25 | c.420C>T p.A140= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV58498480; called by muse, mutect2, varscan2
- GPRC5C | c.51G>A p.Q17= | Silent (SNP) | VAF 85/221 reads (38%) | catalogued as COSV61236723; called by muse, mutect2, varscan2
- GRB14 | c.720C>T p.F240= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- HNF1A | c.612C>T p.F204= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs1488789941; called by muse, mutect2
- HSP90B1 | c.303G>C p.L101= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV55355323; called by muse, mutect2, varscan2
- HSPG2 | c.7149C>T p.V2383= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV65970512; called by muse, mutect2, varscan2
- IGHV2-70 | c.297G>A p.V99= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs138072391; called by muse, varscan2
- KCNN3 | c.957G>T p.L319= | Silent (SNP) | VAF 180/421 reads (43%) | called by muse, mutect2, varscan2
- KEL | c.255C>T p.L85= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- KIF2C | c.792G>A p.R264= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100945786; called by muse, mutect2, varscan2
- KLHL18 | c.888C>T p.L296= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- KLHL42 | c.126G>A p.L42= | Silent (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- L1CAM | c.2838C>T p.G946= | Silent (SNP) | VAF 63/131 reads (48%) | catalogued as rs374991970; called by muse, mutect2, varscan2
- LAMA2 | c.1515C>T p.F505= | Silent (SNP) | VAF 194/425 reads (46%) | called by muse, mutect2, varscan2
- LRP5 | c.3732C>G p.L1244= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as COSV53712964; called by muse, mutect2, varscan2
- LRRC28 | c.648G>T p.L216= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV57335041; called by muse, mutect2, varscan2
- LY6G5B | c.546C>T p.L182= | Silent (SNP) | VAF 188/374 reads (50%) | called by muse, mutect2, varscan2
- LY6G6E | c.211C>T p.L71= | Silent (SNP) | VAF 107/227 reads (47%) | called by muse, mutect2, varscan2
- MACF1 | c.13029G>A p.L4343= (on ENST00000372915; = p.L2276= on NM_012090.5) | Silent (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- MACF1 | c.14871G>A p.V4957= (on ENST00000372915; = p.V2890= on NM_012090.5) | Silent (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- MAP3K21 | c.2970G>A p.E990= | Silent (SNP) | VAF 85/219 reads (39%) | catalogued as rs371713528; called by muse, mutect2, varscan2
- MARCHF4 | c.582C>T p.I194= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs1432309535, COSV99814107; called by muse, mutect2
- MAST4 | c.2574T>C p.F858= (on ENST00000403625 / NM_001164664.2; = p.F669= on NM_015183.3) | Silent (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- MATN1 | c.918C>T p.D306= | Silent (SNP) | VAF 88/180 reads (49%) | catalogued as rs201517537; called by muse, mutect2, varscan2
- MCHR2 | c.828G>A p.Q276= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as COSV56001357, COSV56002346; called by muse, mutect2, varscan2
- MRC1 | c.117G>A p.V39= | Silent (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- MROH1 | c.4140G>T p.R1380= | Silent (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- MRPL48 | c.69C>T p.L23= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- MYH1 | c.576C>T p.V192= | Silent (SNP) | VAF 124/132 reads (94%) | catalogued as rs1330428314, COSV99876715; called by muse, mutect2, varscan2
- MYO10 | c.5787G>A p.R1929= | Silent (SNP) | VAF 98/193 reads (51%) | called by muse, mutect2, varscan2
- MYO18B | c.4077G>A p.L1359= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- NDRG3 | c.1029C>T p.F343= (on ENST00000349004 / NM_032013.4; = p.F331= on NM_022477.4) | Silent (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- NEK4 | c.225A>G p.G75= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- NLRP6 | c.2328G>C p.L776= | Silent (SNP) | VAF 56/115 reads (49%) | called by muse, mutect2, varscan2
- NPBWR1 | c.636C>T p.F212= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV58695530; called by muse, mutect2, varscan2
- NR6A1 | c.252C>T p.F84= (on ENST00000487099 / NM_033334.4; = p.F80= on NM_001489.5) | Silent (SNP) | VAF 98/192 reads (51%) | catalogued as COSV60631265; called by muse, mutect2, varscan2
- NRK | c.1425C>T p.A475= | Silent (SNP) | VAF 111/217 reads (51%) | called by muse, mutect2, varscan2
- NYNRIN | c.4542C>G p.L1514= | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as rs1171633495, COSV66841461; called by muse, mutect2, varscan2
- OPRL1 | c.978C>T p.F326= | Silent (SNP) | VAF 122/264 reads (46%) | catalogued as rs1445675121; called by muse, mutect2, varscan2
- OR1K1 | c.48G>A p.L16= | Silent (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- OR52A5 | c.870C>T p.L290= | Silent (SNP) | VAF 267/564 reads (47%) | called by muse, mutect2, varscan2
- OSCAR | c.450G>A p.V150= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs916915019; called by muse, mutect2, varscan2
- PABPC4 | c.93C>T p.F31= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as rs374479943; called by muse, mutect2, varscan2
- PAPPA | c.636G>A p.V212= | Silent (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1707C>T p.P569= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs765992004, COSV53962723; called by mutect2, varscan2
- PCDHGC3 | c.1464G>A p.Q488= | Silent (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- PCNT | c.4773C>T p.I1591= | Silent (SNP) | VAF 62/140 reads (44%) | catalogued as rs375111791; called by muse, mutect2, varscan2
- PIK3CG | c.1212C>T p.F404= | Silent (SNP) | VAF 76/143 reads (53%) | called by muse, mutect2, varscan2
- POLE | c.3735C>T p.L1245= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- PPP6R3 | c.348G>A p.L116= | Silent (SNP) | VAF 136/279 reads (49%) | called by muse, mutect2, varscan2
- PTGER3 | c.1053G>A p.K351= | Silent (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2409T>A p.A803= | Silent (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- RASGEF1A | c.1239C>T p.I413= | Silent (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- ROCK2 | c.987C>T p.I329= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV55084323; called by muse, mutect2, varscan2
- ROS1 | c.1431C>T p.F477= | Silent (SNP) | VAF 89/218 reads (41%) | catalogued as rs550021694; called by muse, mutect2, varscan2
- RPL12 | c.246C>T p.I82= | Silent (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- RPN2 | c.1443C>G p.L481= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- SALL2 | c.723C>G p.L241= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV58102478; called by muse, varscan2
- SARDH | c.2106G>C p.L702= | Silent (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- SCN7A | c.3624C>T p.I1208= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV101313083; called by muse, mutect2
- SH3TC1 | c.1362G>A p.K454= | Silent (SNP) | VAF 95/185 reads (51%) | called by muse, mutect2, varscan2
- SOCS3 | c.519G>A p.K173= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- SOGA3 | c.1065G>A p.E355= | Silent (SNP) | VAF 52/134 reads (39%) | called by muse, varscan2
- SPTAN1 | c.2007G>A p.L669= | Silent (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- TLL1 | c.270A>C p.G90= | Silent (SNP) | VAF 67/151 reads (44%) | called by muse, mutect2, varscan2
- TMEM252 | c.512G>A p.*171= | Silent (SNP) | VAF 55/92 reads (60%) | called by muse, mutect2, varscan2
- TMEM259 | c.846C>T p.F282= | Silent (SNP) | VAF 181/358 reads (51%) | called by muse, mutect2, varscan2
- TMEM41B | c.591C>T p.L197= | Silent (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- TMX3 | c.1356G>A p.K452= | Silent (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- TRANK1 | c.1833G>A p.R611= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- TRHR | c.735G>A p.L245= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- TRIL | c.963C>T p.F321= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as rs1432371451; called by muse, mutect2, varscan2
- TRIO | c.3819G>A p.V1273= | Silent (SNP) | VAF 38/126 reads (30%) | called by muse, mutect2, varscan2
- TRUB1 | c.42G>A p.L14= | Silent (SNP) | VAF 159/312 reads (51%) | called by muse, mutect2, varscan2
- TSKU | c.456G>A p.T152= | Silent (SNP) | VAF 46/654 reads (7%) | catalogued as rs1169272055, COSV100290108; called by muse, mutect2
- UBQLN3 | c.1623C>T p.L541= | Silent (SNP) | VAF 136/288 reads (47%) | catalogued as rs776156868; called by muse, mutect2, varscan2
- USP42 | c.258C>T p.I86= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs749679130, COSV60359569; called by muse, mutect2, varscan2
- UTP6 | c.39C>A p.L13= | Silent (SNP) | VAF 115/268 reads (43%) | catalogued as COSV99911901; called by muse, mutect2, varscan2
- VPS13C | c.8181C>T p.F2727= (on ENST00000644861 / NM_020821.3; = p.F2684= on NM_017684.5) | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV51119978; called by muse, mutect2, varscan2
- WDFY3 | c.2913G>A p.L971= | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as rs1026403025; called by muse, mutect2, varscan2
- XBP1 | c.58C>T p.L20= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs1436661994; called by muse, mutect2, varscan2
- XKR6 | c.1881C>T p.D627= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs200925376, COSV100440353; called by muse, mutect2, varscan2
- ZNF484 | c.2454A>G p.Q818= | Silent (SNP) | VAF 101/378 reads (27%) | called by muse, mutect2, varscan2
- ZNF490 | c.255G>A p.V85= | Silent (SNP) | VAF 105/241 reads (44%) | catalogued as rs376155605; called by muse, mutect2, varscan2
- ZNF507 | c.2067C>T p.I689= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV61333503; called by muse, mutect2
- ZNF727 | c.1077G>A p.K359= | Silent (SNP) | VAF 96/197 reads (49%) | called by muse, mutect2, varscan2
- ABAT | c.*2677G>A | 3'UTR (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- ABR | c.*287G>C | 3'UTR (SNP) | VAF 85/162 reads (52%) | called by muse, mutect2, varscan2
- ABTB1 | c.-25C>T | 5'UTR (SNP) | VAF 79/174 reads (45%) | catalogued as rs768164213, COSV99229801; called by muse, mutect2, varscan2
- AC007663.1 | n.335C>T | RNA (SNP) | VAF 29/100 reads (29%) | catalogued as rs1224642738; called by muse, mutect2, varscan2
- AC008080.1 | n.786G>A | RNA (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- AC024940.1 | n.5339G>A | RNA (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- AC233702.1 | n.397G>A | RNA (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ACOX1 | c.430+37C>T | Intron (SNP) | VAF 11/30 reads (37%) | catalogued as rs1172507415; called by muse, mutect2, varscan2
- ACSM2A | c.-4G>C | 5'UTR (SNP) | VAF 8/224 reads (4%) | called by muse, mutect2
- ACTB | c.-27-222A>C | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, varscan2
- ACTR2 | c.*210A>G | 3'UTR (SNP) | VAF 56/99 reads (57%) | called by muse, mutect2, varscan2
- ACVRL1 | c.-5-19C>G | Intron (SNP) | VAF 79/236 reads (33%) | called by muse, mutect2, varscan2
- ADAM28 | c.-37G>A | 5'UTR (SNP) | VAF 88/104 reads (85%) | catalogued as rs576541353; called by muse, mutect2, varscan2
- ADAP2 | c.*711G>A | 3'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- ADAR | c.-935G>A | 5'UTR (SNP) | VAF 47/84 reads (56%) | catalogued as rs1297318149, COSV52719579; called by muse, mutect2, varscan2
- ADD2 | c.*1580G>A | 3'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- ADGRG6 | c.*1151G>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- ADH1B | c.*320C>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- ADH5 | chr4:99088750 G>A | 5'Flank (SNP) | VAF 88/217 reads (41%) | catalogued as rs533696123; called by muse, mutect2, varscan2
- AKT3 | c.*2041C>T | 3'UTR (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- AL356585.2 | n.1803G>A | RNA (SNP) | VAF 30/33 reads (91%) | catalogued as rs1194538916; called by muse, mutect2, varscan2
- AL645929.2 | chr6:29888577 G>A | 5'Flank (SNP) | VAF 32/71 reads (45%) | catalogued as rs1363612810; called by muse, mutect2, varscan2
- ALOX5AP | c.-24C>T | 5'UTR (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25165380 G>A | 3'Flank (SNP) | VAF 11/107 reads (10%) | catalogued as rs897116868; called by muse, mutect2, varscan2
- AMPD3 | chr11:10450724 C>T | 5'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- ANKRD28 | c.-214C>T | 5'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- ANO6 | chr12:45216006 C>T | 5'Flank (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- ANP32A | c.*1314G>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- AP001122.1 | n.512G>T | RNA (SNP) | VAF 76/174 reads (44%) | called by muse, mutect2, varscan2
- AP1AR | chr4:112231745 C>T | 5'Flank (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- APEH | c.-24C>T | 5'UTR (SNP) | VAF 39/91 reads (43%) | catalogued as rs1302881634; called by muse, mutect2, varscan2
- APLP1 | c.1580-51G>C | Intron (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- APOF | c.-9C>T | 5'UTR (SNP) | VAF 196/396 reads (49%) | called by muse, mutect2, varscan2
- AQP6 | c.403-55C>T | Intron (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2
- ARHGAP4 | c.2157-20C>T | Intron (SNP) | VAF 57/119 reads (48%) | catalogued as rs1439320119, COSV61686468; called by muse, mutect2
- ARHGEF7 | c.1789-104C>T | Intron (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- ARMC5 | c.1865-142G>A | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- ARRDC3 | c.-175C>T | 5'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs1393538762; called by muse, mutect2, varscan2
- ATG4A | chrX:108091721 C>T | 5'Flank (SNP) | VAF 123/300 reads (41%) | called by muse, mutect2, varscan2
- ATL2 | c.1633-394C>T | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- AZIN1 | chr8:102864611 G>A | 5'Flank (SNP) | VAF 9/13 reads (69%) | catalogued as rs1036138157; called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031446 G>C | 5'Flank (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- BATF3 | c.*148G>A | 3'UTR (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- BAZ1A | c.*29G>A | 3'UTR (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- BCL11A | c.*1782T>A | 3'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021114 G>A | 5'Flank (SNP) | VAF 52/132 reads (39%) | catalogued as rs527304462, COSV104379344, COSV55846292, COSV55849070; called by muse, varscan2
- BICRAL | c.*161C>G | 3'UTR (SNP) | VAF 49/85 reads (58%) | called by muse, mutect2, varscan2
- BRI3BP | c.*4671G>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- BST1 | c.852-125C>G | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- BTBD3 | c.*2197G>A | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- C12orf4 | c.*308G>C | 3'UTR (SNP) | VAF 68/137 reads (50%) | called by muse, mutect2, varscan2
- C1orf115 | c.-21C>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- C2CD2 | c.*3771G>A | 3'UTR (SNP) | VAF 25/123 reads (20%) | catalogued as rs977015060; called by muse, mutect2
- C3orf14 | c.*19C>T | 3'UTR (SNP) | VAF 159/343 reads (46%) | called by muse, mutect2, varscan2
- C4BPB | c.-44G>T | 5'UTR (SNP) | VAF 155/349 reads (44%) | called by muse, mutect2, varscan2
- CALN1 | c.*1553C>A | 3'UTR (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- CBFA2T2 | c.*2447G>A | 3'UTR (SNP) | VAF 33/78 reads (42%) | catalogued as rs372233009; called by muse, mutect2, varscan2
- CBLN1 | c.-1G>A | 5'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs903251534; called by muse, mutect2, varscan2
- CCDC85B | c.*3G>A | 3'UTR (SNP) | VAF 61/169 reads (36%) | called by muse, mutect2, varscan2
- CCL4 | c.*80C>G | 3'UTR (SNP) | VAF 168/307 reads (55%) | called by muse, mutect2, varscan2
- CCNC | c.439-65G>A | Intron (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- CD2AP | c.-229G>A | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- CDON | c.*1665G>C | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- CELF5 | c.*40+111G>A | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- CEP83 | c.*344C>T | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- CGN | c.*1161C>T | 3'UTR (SNP) | VAF 45/89 reads (51%) | catalogued as rs948926598; called by muse, mutect2, varscan2
- CHCHD7 | c.-17+983C>G | Intron (SNP) | VAF 196/452 reads (43%) | called by muse, mutect2, varscan2
- CHL1 | c.*1044G>C | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- CHORDC1 | c.*466C>G | 3'UTR (SNP) | VAF 56/217 reads (26%) | called by muse, mutect2, varscan2
- CHRNA1 | c.853+730G>C | Intron (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- CHST3 | c.*2186G>C | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- CISD2 | c.*1550G>A | 3'UTR (SNP) | VAF 90/202 reads (45%) | called by muse, varscan2
- CLDN8 | c.*984G>A | 3'UTR (SNP) | VAF 66/131 reads (50%) | called by muse, mutect2, varscan2
- CLNK | c.*3265G>T | 3'UTR (SNP) | VAF 23/68 reads (34%) | catalogued as rs1267154779; called by muse, mutect2, varscan2
- CNOT2 | c.569+94C>A | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- CNR2 | c.*670G>A | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- COG7 | chr16:23453203 C>G | 5'Flank (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- COL21A1 | c.1543-71G>A | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2
- CPAMD8 | c.815-138A>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- CPNE6 | c.-70G>A | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- CRB2 | c.3389+31G>A | Intron (SNP) | VAF 54/84 reads (64%) | catalogued as rs1418093582; called by muse, mutect2, varscan2
- CTSO | c.*1839G>A | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- CUBN | c.593+561G>A | Intron (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2
- CYB561A3 | c.*669G>A | 3'UTR (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- CYB561A3 | c.*491G>A | 3'UTR (SNP) | VAF 91/180 reads (51%) | catalogued as rs1396832947; called by muse, mutect2, varscan2
- CYP4B1 | c.*596C>T | 3'UTR (SNP) | VAF 28/88 reads (32%) | catalogued as rs1223551960; called by muse, mutect2, varscan2
- CYTH3 | c.449+694C>T | Intron (SNP) | VAF 29/82 reads (35%) | catalogued as rs140656311; called by muse, mutect2, varscan2
- DBN1 | c.-108G>A | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- DCP1B | c.-1G>A | 5'UTR (SNP) | VAF 102/232 reads (44%) | catalogued as rs771032950; called by muse, mutect2, varscan2
- DCTN5 | c.118-7615G>A | Intron (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*594C>A | 3'UTR (SNP) | VAF 50/57 reads (88%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.-13G>A | 5'UTR (SNP) | VAF 41/87 reads (47%) | catalogued as rs1467920409; called by muse, mutect2, varscan2
- DEFB130C | chr11:71865513 G>A | 3'Flank (SNP) | VAF 77/155 reads (50%) | called by muse, mutect2, varscan2
- DGKG | c.792+91C>G | Intron (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- DNAJC6 | c.-132C>T | 5'UTR (SNP) | VAF 68/161 reads (42%) | called by muse, mutect2, varscan2
- DNAJC6 | c.*2058C>G | 3'UTR (SNP) | VAF 69/143 reads (48%) | called by muse, mutect2, varscan2
- DPP4 | chr2:162077276 C>T | 5'Flank (SNP) | VAF 69/147 reads (47%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.387C>G | RNA (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- DPY19L4 | c.*3283G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- DST | c.4297-4312A>G | Intron (SNP) | VAF 17/358 reads (5%) | called by muse, mutect2
- DTX1 | c.-212C>T | 5'UTR (SNP) | VAF 73/139 reads (53%) | called by muse, mutect2, varscan2
- ECPAS | c.*1056C>T | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- EIF1AX | c.*1263G>A | 3'UTR (SNP) | VAF 91/112 reads (81%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*2249G>C | 3'UTR (SNP) | VAF 166/380 reads (44%) | called by muse, varscan2
- ELP3 | c.*715G>A | 3'UTR (SNP) | VAF 84/88 reads (95%) | catalogued as rs1015202106; called by muse, mutect2, varscan2
- ENO2 | c.-12-63G>A | Intron (SNP) | VAF 141/328 reads (43%) | called by muse, mutect2, varscan2
- ENTPD1 | c.*51G>A | 3'UTR (SNP) | VAF 61/355 reads (17%) | called by muse, mutect2, varscan2
- ERBIN | c.*2941C>G | 3'UTR (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- ERG | chr21:38382678 C>G | 3'Flank (SNP) | VAF 10/336 reads (3%) | called by muse, mutect2
- ERI2 | chr16:20806630 G>T | 5'Flank (SNP) | VAF 9/15 reads (60%) | catalogued as COSV54472246; called by muse, mutect2
- ERLIN1 | c.-12+14G>A | Intron (SNP) | VAF 72/137 reads (53%) | catalogued as COSV64917152; called by muse, mutect2, varscan2
- FADD | c.-83G>A | 5'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- FAM234A | c.*270C>T | 3'UTR (SNP) | VAF 119/123 reads (97%) | called by muse, mutect2, varscan2
- FBXL17 | c.*549C>T | 3'UTR (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- FCGR2A | c.86-69C>T | Intron (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- FIGN | c.*6499C>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- FKBP1C | c.*987C>T | 3'UTR (SNP) | VAF 117/233 reads (50%) | called by muse, mutect2, varscan2
- FOXA1 | c.*1023G>C | 3'UTR (SNP) | VAF 73/179 reads (41%) | called by muse, mutect2, varscan2
- FOXP4 | chr6:41601822 G>A | 3'Flank (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- FRMD3 | c.1070+1140C>G | Intron (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- FRMD5 | c.*1036C>T | 3'UTR (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- FZD4 | c.*4707C>T | 3'UTR (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- GATA6 | c.*454C>G | 3'UTR (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- GGNBP2 | c.93+168C>T | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- GLB1L3 | chr11:134274377 C>G | 5'Flank (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- GLIS3 | c.*176C>T | 3'UTR (SNP) | VAF 46/97 reads (47%) | catalogued as rs1165728191; called by muse, mutect2, varscan2
- GLS | c.386+88G>C | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- GNPDA2 | c.769+606A>C | Intron (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- GOLGA1 | c.-92G>C | 5'UTR (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- GOLPH3L | c.*1591G>C | 3'UTR (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- GPATCH2 | c.*2639G>A | 3'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- GRIA4 | c.1269+1727C>T | Intron (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- GSN | c.667-373C>T | Intron (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- GYG1 | c.*4498G>A | 3'UTR (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- H1-10 | c.*83C>G | 3'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- H2BC21 | c.*1681T>A | 3'UTR (SNP) | VAF 43/139 reads (31%) | called by muse, mutect2, varscan2
- HBEGF | c.-14C>G | 5'UTR (SNP) | VAF 87/196 reads (44%) | catalogued as rs1474791207, COSV99138200; called by muse, mutect2, varscan2
- HDGF | chr1:156752437 G>A | 5'Flank (SNP) | VAF 183/427 reads (43%) | catalogued as rs753357751; called by muse, mutect2, varscan2
- HEPH | c.-425G>A | 5'UTR (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2
- HEXB | c.1418-27G>A | Intron (SNP) | VAF 30/78 reads (38%) | catalogued as rs1241467219; called by muse, mutect2, varscan2
- HHAT | c.*1793C>G | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- HIKESHI | c.540-137C>G | Intron (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- HIVEP1 | c.40+4648G>T | Intron (SNP) | VAF 302/643 reads (47%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.98-233C>T | Intron (SNP) | VAF 23/42 reads (55%) | catalogued as rs993951259; called by muse, mutect2
- HOXB3 | c.-318C>T | 5'UTR (SNP) | VAF 16/362 reads (4%) | catalogued as rs1167139548; called by muse, mutect2
- HSPA8 | chr11:123061459 C>T | 5'Flank (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2
- ID1 | c.*161G>A | 3'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs1272059290; called by muse, mutect2, varscan2
- ID2 | c.-107C>A | 5'UTR (SNP) | VAF 25/72 reads (35%) | catalogued as COSV52170980, COSV99301073; called by muse, mutect2, varscan2
- IFIT1 | c.5+442C>T | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*4001G>A | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1112G>T | Intron (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1391G>C | Intron (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- IL1RL1 | c.970+81C>G | Intron (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- INSIG2 | c.*1275G>C | 3'UTR (SNP) | VAF 54/104 reads (52%) | called by muse, mutect2, varscan2
- IQCE | c.*3128C>T | 3'UTR (SNP) | VAF 96/180 reads (53%) | catalogued as rs922438192; called by muse, mutect2, varscan2
- IRAG1 | c.67+5885C>T | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- IRAK1BP1 | c.*4538C>G | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- IRF7 | c.492+23C>G | Intron (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- IRX6 | c.-565G>T | 5'UTR (SNP) | VAF 96/230 reads (42%) | called by muse, mutect2, varscan2
- ITFG2 | c.193-94G>A | Intron (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- ITGAX | c.861+44C>G | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- ITGB6 | c.*1314G>C | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- ITGB8 | c.-76G>A | 5'UTR (SNP) | VAF 12/15 reads (80%) | called by muse, mutect2, varscan2
- KCNC1 | c.*223G>C | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- KCNH2 | c.-115C>T | 5'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- KCNMB3 | chr3:179240214 G>A | 3'Flank (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- KCTD6 | c.-196C>G | 5'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- KCTD8 | c.*144T>G | 3'UTR (SNP) | VAF 83/177 reads (47%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.-179C>G | 5'UTR (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- KIAA1586 | c.21+10C>T | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2
- KLC4 | c.-26+551C>G | Intron (SNP) | VAF 149/408 reads (37%) | catalogued as rs1368894324, COSV99432436; called by muse, mutect2, varscan2
- KLHL6 | c.*3011C>G | 3'UTR (SNP) | VAF 120/225 reads (53%) | called by muse, mutect2, varscan2
- KLHL7 | c.1380-120G>A | Intron (SNP) | VAF 10/22 reads (45%) | catalogued as rs558478508; called by muse, varscan2
- KLRG2 | c.*563C>T | 3'UTR (SNP) | VAF 182/473 reads (38%) | called by muse, mutect2, varscan2
- KMT2A | c.*1026C>T | 3'UTR (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- KNDC1 | c.-11G>A | 5'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- KNG1 | c.*1514G>A | 3'UTR (SNP) | VAF 186/442 reads (42%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.*96C>G | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- LAT | c.581-153C>G | Intron (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- LGALS1 | c.-59C>T | 5'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- LIAS | chr4:39477665 G>C | 3'Flank (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- LINC02551 | n.1228G>A | RNA (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- LINGO1 | c.*742C>T | 3'UTR (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- LRIF1 | chr1:110963988 C>T | 5'Flank (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- LRRC37BP1 | n.1225G>C | RNA (SNP) | VAF 127/296 reads (43%) | called by muse, mutect2, varscan2
- LRRC8C | c.139-6324C>T | Intron (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- LRRK2 | c.*795C>T | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- LTB | c.208+25C>T | Intron (SNP) | VAF 170/340 reads (50%) | catalogued as rs769131084; called by muse, varscan2
- LTB | c.163-108G>C | Intron (SNP) | VAF 226/498 reads (45%) | called by muse, varscan2
- LZTS3 | c.*1589G>A | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- MAD2L2 | c.-13+95C>G | Intron (SNP) | VAF 64/71 reads (90%) | catalogued as rs368736707; called by muse, mutect2, varscan2
- MARCHF4 | c.-1746C>T | 5'UTR (SNP) | VAF 23/45 reads (51%) | catalogued as rs1224456598; called by muse, mutect2, varscan2
- MAST2 | c.-211G>A | 5'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- MCM2 | c.1428+1861G>A | Intron (SNP) | VAF 84/186 reads (45%) | called by muse, mutect2, varscan2
- MCM9 | c.1150+1038G>A | Intron (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- MED22 | c.*2098C>T | 3'UTR (SNP) | VAF 35/62 reads (56%) | catalogued as rs1462230428; called by muse, mutect2, varscan2
- METTL2B | c.*759G>A | 3'UTR (SNP) | VAF 43/92 reads (47%) | catalogued as rs1274397530; called by muse, mutect2, varscan2
- MFSD4B | c.*1439G>T | 3'UTR (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- MGMT | c.-24C>T | 5'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- MIF | c.-62C>T | 5'UTR (SNP) | VAF 97/200 reads (49%) | catalogued as rs201326009; called by muse, mutect2, varscan2
- MIR133A2 | chr20:62565046 G>T | 3'Flank (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- MKLN1 | c.*2793C>G | 3'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- MKRN1 | c.*181T>C | 3'UTR (SNP) | VAF 75/156 reads (48%) | called by muse, mutect2, varscan2
- MLC1 | c.*2165G>A | 3'UTR (SNP) | VAF 44/100 reads (44%) | catalogued as rs1339763256; called by muse, mutect2, varscan2
- MME | c.*2245T>C | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- MMGT1 | c.*1343T>G | 3'UTR (SNP) | VAF 44/80 reads (55%) | called by muse, mutect2, varscan2
- MMP9 | c.-11C>G | 5'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- MORC2 | c.-410C>T | 5'UTR (SNP) | VAF 30/63 reads (48%) | catalogued as rs1396157946; called by muse, mutect2, varscan2
- MPV17L | c.311-1347C>G | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs998348883; called by muse, mutect2, varscan2
- MRNIP | c.126+1960C>T | Intron (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- MS4A10 | c.*187G>A | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- MSC | c.*665C>G | 3'UTR (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- MT3 | c.*27T>C | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- MTMR2 | c.*1150C>G | 3'UTR (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- MZB1 | c.*258G>A | 3'UTR (SNP) | VAF 81/165 reads (49%) | called by muse, mutect2, varscan2
- N4BP2 | c.*2847G>A | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- NAA50 | c.*1007C>T | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- NAAA | c.207-75C>T | Intron (SNP) | VAF 60/137 reads (44%) | catalogued as rs548755579, COSV99715910; called by muse, mutect2, varscan2
- NANOG | c.-182C>T | 5'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- NEBL | c.*883C>G | 3'UTR (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- NEDD4 | c.*1807C>T | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- NEK6 | c.*1958C>T | 3'UTR (SNP) | VAF 119/294 reads (40%) | called by muse, mutect2, varscan2
- NELFA | c.244-886C>T | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2
- NEUROD1 | c.*472T>C | 3'UTR (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- NFIB | chr9:14314120 G>A | 5'Flank (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- NICN1 | c.*1010G>A | 3'UTR (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- NONO | c.*304C>T | 3'UTR (SNP) | VAF 95/224 reads (42%) | called by muse, mutect2, varscan2
- NOTCH2 | c.*2126C>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs975735339; called by muse, mutect2, varscan2
- NOTCH2NLC | chr1:149466554 G>A | 3'Flank (SNP) | VAF 104/232 reads (45%) | called by muse, mutect2, varscan2
- NOVA1 | c.280+45644G>A | Intron (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- NSUN5 | chr7:73298379 G>C | 3'Flank (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- NT5C2 | c.102-13885G>A | Intron (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- NUDCD3 | c.*1151G>A | 3'UTR (SNP) | VAF 60/152 reads (39%) | catalogued as rs1311142702; called by muse, mutect2, varscan2
- NUP107 | chr12:68686972 C>G | 5'Flank (SNP) | VAF 58/138 reads (42%) | catalogued as COSV99972071; called by muse, mutect2
- NXPH3 | c.*298G>A | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- OSCAR | c.*253C>T | 3'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- OTC | c.*144G>A | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- OXR1 | c.-56G>A | 5'UTR (SNP) | VAF 201/512 reads (39%) | called by muse, mutect2, varscan2
- P3H2 | c.*782C>T | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- PAFAH1B2 | c.*7C>G | 3'UTR (SNP) | VAF 46/366 reads (13%) | called by muse, mutect2, varscan2
- PAN3 | c.*1632G>C | 3'UTR (SNP) | VAF 46/55 reads (84%) | called by muse, mutect2, varscan2
- PARM1 | c.-155C>A | 5'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- PCIF1 | c.*125C>T | 3'UTR (SNP) | VAF 17/381 reads (4%) | called by muse, mutect2
- PCMTD1 | c.*2554G>A | 3'UTR (SNP) | VAF 181/744 reads (24%) | called by muse, mutect2, varscan2
- PCMTD1 | c.410+95C>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
- PCNX2 | c.4077-189G>A | Intron (SNP) | VAF 71/479 reads (15%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.*180C>G | 3'UTR (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99930912; called by muse, mutect2, varscan2
- PDE6C | c.*508C>G | 3'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- PDXDC1 | c.*1000G>A | 3'UTR (SNP) | VAF 33/96 reads (34%) | catalogued as rs1018800514; called by muse, mutect2, varscan2
- PDXK | c.143-3644G>A | Intron (SNP) | VAF 79/153 reads (52%) | called by muse, mutect2, varscan2
- PFDN6 | c.-78G>A | 5'UTR (SNP) | VAF 88/186 reads (47%) | catalogued as COSV101004784; called by muse, mutect2, varscan2
- PHGDH | c.139-88C>T | Intron (SNP) | VAF 160/181 reads (88%) | catalogued as rs587710790; called by muse, mutect2, varscan2
- PHLDB2 | c.1720-2503G>A | Intron (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- PI4KA | c.-63G>A | 5'UTR (SNP) | VAF 8/154 reads (5%) | catalogued as rs1410550687; called by muse, mutect2
- PIGH | c.*295T>C | 3'UTR (SNP) | VAF 43/133 reads (32%) | called by muse, mutect2, varscan2
- PITPNB | c.*392G>A | 3'UTR (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- PLEKHM1 | chr17:45490731 C>T | 5'Flank (SNP) | VAF 9/22 reads (41%) | catalogued as rs760651003; called by muse, mutect2, varscan2
- POFUT1 | c.*1812G>C | 3'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- POLG2 | c.-27G>C | 5'UTR (SNP) | VAF 128/222 reads (58%) | catalogued as rs1403336346, COSV99858213; called by muse, mutect2, varscan2
- PON1 | c.*796G>A | 3'UTR (SNP) | VAF 6/139 reads (4%) | catalogued as rs1007583696; called by muse, mutect2
- POU2F1 | c.*10379C>T | 3'UTR (SNP) | VAF 55/112 reads (49%) | catalogued as COSV54814392; called by muse, mutect2, varscan2
- PPP1R12A | c.*290C>T | 3'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- PPP6R1 | c.1477+38G>A | Intron (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- PREB | c.-176G>A | 5'UTR (SNP) | VAF 72/291 reads (25%) | catalogued as rs372436206; called by muse, mutect2, varscan2
- PRPF39 | c.451-52C>T | Intron (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- PRR16 | c.*363C>G | 3'UTR (SNP) | VAF 6/118 reads (5%) | catalogued as COSV65405241; called by muse, mutect2
- PRSS35 | c.*842C>T | 3'UTR (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- PSMF1 | c.-21-45C>G | Intron (SNP) | VAF 153/374 reads (41%) | catalogued as rs890893667; called by muse, mutect2
- PTAFR | chr1:28148042 T>G | 3'Flank (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- PTGDR2 | c.*977C>T | 3'UTR (SNP) | VAF 55/135 reads (41%) | called by muse, mutect2, varscan2
- PTGFRN | c.-51G>A | 5'UTR (SNP) | VAF 14/16 reads (88%) | called by muse, mutect2, varscan2
- PTGR2 | chr14:73886682 G>A | 3'Flank (SNP) | VAF 102/106 reads (96%) | called by muse, mutect2, varscan2
- PTPN21 | c.*1821A>G | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- PWP1 | c.-80G>A | 5'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- PXDN | c.*2101C>T | 3'UTR (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- QSOX1 | c.*6407C>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- RAB10 | c.-46G>A | 5'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99265888; called by muse, mutect2, varscan2
- RAB6A | c.-404G>A | 5'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- RAD50 | c.1793+886C>T | Intron (SNP) | VAF 79/161 reads (49%) | called by muse, mutect2, varscan2
- RAD51AP1 | c.*590C>G | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- RAET1E | chr6:149883828 C>G | 3'Flank (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- RASGEF1B | c.439-2809C>G | Intron (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- RBAK | c.*1542G>T | 3'UTR (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- REEP6 | c.-35G>C | 5'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- REPS1 | c.*98C>T | 3'UTR (SNP) | VAF 104/210 reads (50%) | called by muse, mutect2, varscan2
- RFTN1 | c.1030+59G>A | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2
- RHBDD1 | c.*720C>T | 3'UTR (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20613G>A | Intron (SNP) | VAF 188/442 reads (43%) | catalogued as rs866791890; called by muse, mutect2, varscan2
- RIPPLY2 | c.-76C>T | 5'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- RNF157 | c.793-128C>G | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, varscan2
- RNF217 | c.*7298G>T | 3'UTR (SNP) | VAF 30/76 reads (39%) | catalogued as COSV72875262; called by muse, mutect2, varscan2
- RNMT | c.*4544C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1641G>T | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100139694; called by muse, mutect2, varscan2
- RPL37 | c.*5276C>T | 3'UTR (SNP) | VAF 119/271 reads (44%) | catalogued as rs1248100033; called by muse, mutect2, varscan2
- RPL5 | c.-32C>T | 5'UTR (SNP) | VAF 104/108 reads (96%) | catalogued as rs746539975, COSV59872914; called by muse, mutect2, varscan2
- RPS6KA6 | c.-129G>A | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- RRAGD | c.*319C>G | 3'UTR (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- RSPO3 | c.98-18C>G | Intron (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- RUFY3 | c.*1312C>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as rs1287880707; called by muse, mutect2
- RUFY3 | c.*285C>G | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- SAE1 | c.733+10314C>T | Intron (SNP) | VAF 143/291 reads (49%) | called by muse, mutect2, varscan2
- SCARA3 | c.*220C>T | 3'UTR (SNP) | VAF 29/30 reads (97%) | catalogued as rs1246144481; called by muse, mutect2, varscan2
- SDC1 | c.*1939G>A | 3'UTR (SNP) | VAF 51/143 reads (36%) | catalogued as rs770976739; called by muse, mutect2, varscan2
- SDE2 | c.*725C>T | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SEC61A2 | c.-39G>C | 5'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- SEC62 | c.*4121C>T | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- SELENOK | chr3:53891911 G>A | 5'Flank (SNP) | VAF 10/305 reads (3%) | called by muse, mutect2
- SEMA4C | c.1444-13G>A | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as rs376901129; called by mutect2, varscan2
- SEPTIN7 | c.*398C>T | 3'UTR (SNP) | VAF 186/392 reads (47%) | called by muse, varscan2
- SF3B5 | c.*194G>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- SGCE | c.*57C>T | 3'UTR (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- SGK2 | c.778-141G>A | Intron (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- SH3TC2 | c.*191G>T | 3'UTR (SNP) | VAF 68/134 reads (51%) | called by muse, mutect2, varscan2
- SHF | c.303+144C>T | Intron (SNP) | VAF 9/17 reads (53%) | catalogued as rs1354810757; called by muse, mutect2, varscan2
- SLC18A2 | c.607+45G>A | Intron (SNP) | VAF 77/163 reads (47%) | catalogued as COSV100042178; called by muse, mutect2, varscan2
- SLC25A30 | chr13:45390696 C>T | 3'Flank (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- SLC25A48 | c.679+654C>G | Intron (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2, varscan2
- SLC2A1 | c.516+51C>T | Intron (SNP) | VAF 73/138 reads (53%) | catalogued as rs758783636; called by muse, mutect2, varscan2
- SLC2A13 | c.-170C>T | 5'UTR (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- SLC34A1 | c.936+1641G>A | Intron (SNP) | VAF 97/180 reads (54%) | catalogued as rs895698067; called by muse, mutect2, varscan2
- SLC35F6 | c.*1079G>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- SLC38A10 | c.626+732C>A | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- SLC38A4 | c.-78G>A | 5'UTR (SNP) | VAF 161/304 reads (53%) | called by muse, mutect2, varscan2
- SLC39A1 | c.-32-17C>T | Intron (SNP) | VAF 143/328 reads (44%) | called by muse, mutect2, varscan2
- SLC4A3 | c.*59C>T | 3'UTR (SNP) | VAF 130/262 reads (50%) | called by muse, mutect2, varscan2
- SLC5A3 | c.*473C>G | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- SLC9A8 | c.*19C>T | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- SNRPD3 | c.*314G>A | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- SNX21 | c.448-2339C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
70 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 70 other) are not listed here.
